Gene-level copy-number profile of tumor specimen ALCH-B46M-TTP1-A from ALCHEMIST case ALCH-B46M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.2 years (23,817 days).
Specimen ALCH-B46M-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0a0d3989-dc13-443f-84a9-b99cd764e892.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B46M-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,748 have no estimate.
https://portal.gdc.cancer.gov/files/4d88d48b-7aed-4cdf-8cfc-9517445e7f8e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 3,699; copy number 2: 50,212; copy number 3: 4,314; copy number 4: 241; copy number 5: 127; copy number 6: 203; copy number 7: 57; copy number 17: 2.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:26,019,884–26,046,118, 2 genes: EXTL1, SLC30A2.
- chr13:113,648,804–113,658,198, 1 gene: ATP4B.
- chr15:25,194,921–25,225,284, 17 genes (within-gene range 0–2): SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 389 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:149,030,127–153,980,186, 99 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:165,122,713–183,812,624, 279 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:181,306,502–181,324,685, 1 gene, copy number 7: AC138035.1.
- chr10:44,712–46,884, 1 gene, copy number 17: AL713922.1.
- chr19:8,302,127–8,343,262, 5 genes, copy number 5 (within-gene range 4–5): CD320, AC010323.1, NDUFA7, RPS28, KANK3.
- chr20:64,327,418–64,327,972, 1 gene, copy number 5: AL137028.1.
- chr21:8,680,538–8,680,934, 1 gene, copy number 17: CR381572.2.
- chr22:18,846,811–18,861,049, 2 genes, copy number 5 (within-gene range 5–9): AC008132.1, BCRP7.

Autosomal genes at a single copy (total copy number 1): 875. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
